Somatic mutation profile of tumor specimen TCGA-3A-A9IH-01A (aliquot TCGA-3A-A9IH-01A-12D-A397-08) from TCGA case TCGA-3A-A9IH, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 66.2 years (24,174 days).
Specimen TCGA-3A-A9IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd9734d0-0adf-41ae-bf88-e41f6cef02f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IH-10A (Blood Derived Normal), aliquot TCGA-3A-A9IH-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8b6b13d-02f8-4585-8600-07e59ebbbdfe

The open-access MAF lists 56 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 11, Frame Shift Ins 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 50/319 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.842dup p.L282Afs*3 | Frame Shift Ins (INS) | VAF 23/58 reads (40%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.428T>A p.V143E | Missense Mutation (SNP) | VAF 74/233 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1511132, COSV52737174, COSV52760297, COSV52868891; called by muse, mutect2, varscan2
- ABCC9 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 117/409 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749786076, COSV53966945; called by muse, mutect2, varscan2
- AC090517.4 | c.1913A>G p.Y638C | Missense Mutation (SNP) | VAF 69/432 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99975124; called by muse, mutect2, varscan2
- ASH1L | c.3079G>A p.A1027T | Missense Mutation (SNP) | VAF 118/435 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100853601; called by muse, mutect2, varscan2
- BEND2 | c.1937G>C p.R646P | Missense Mutation (SNP) | VAF 85/367 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV101192217; called by muse, mutect2, varscan2
- BIRC6 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.644); catalogued as rs1420745785, COSV101428881; called by muse, mutect2, varscan2
- CTSS | c.653A>C p.K218T | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV100935035; called by muse, mutect2, varscan2
- DHRS4 | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 79/1774 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100366023; called by muse, mutect2
- EPB41 | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 137/531 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100549466; called by muse, mutect2, varscan2
- FRY | c.3289A>G p.M1097V | Missense Mutation (SNP) | VAF 88/437 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs776944889, COSV100969909; called by muse, mutect2, varscan2
- GABRB3 | c.383A>T p.K128M | Missense Mutation (SNP) | VAF 139/496 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100158218, COSV100161801; called by muse, mutect2, varscan2
- GAS2L2 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 110/353 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs373436768; called by muse, mutect2, varscan2
- GOLGA1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 99/594 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as rs763536773, COSV100764441, COSV100764446; called by muse, mutect2, varscan2
- HERC1 | c.13810G>T p.V4604L | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101496906; called by muse, mutect2, varscan2
- HMGB2 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 87/457 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99632862; called by muse, mutect2, varscan2
- HYDIN | c.11269G>A p.V3757I | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as rs199890203; called by muse, mutect2, varscan2
- IGBP1P2 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs763860516; called by muse, mutect2, varscan2
- IGKV2D-30 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 60/1349 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs368396735; called by muse, mutect2
- LRRC27 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs1315018827, COSV100689966; called by muse, mutect2
- METTL15 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1208494488, COSV100328777; called by muse, mutect2, varscan2
- MIB1 | c.2521T>C p.S841P | Missense Mutation (SNP) | VAF 69/478 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV99839469; called by muse, mutect2, varscan2
- MUC5AC | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 93/431 reads (22%) | SIFT tolerated (0.09); catalogued as COSV100650695; called by muse, mutect2, varscan2
- MYH1 | c.5378C>T p.T1793M | Missense Mutation (SNP) | VAF 170/506 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs202246274, COSV56846933; called by muse, mutect2, varscan2
- MYO18B | c.2053G>C p.D685H | Missense Mutation (SNP) | VAF 56/434 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100125161; called by muse, varscan2
- NELFB | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1355792091, COSV100547041; called by muse, mutect2, varscan2
- NOTCH4 | c.3112C>G p.H1038D | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1449977400, COSV100901023; called by muse, mutect2, varscan2
- NRK | c.3916A>G p.K1306E | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV99689164; called by muse, mutect2
- OR2G2 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 84/514 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs372540193, COSV100189977; called by muse, mutect2, varscan2
- PPIP5K1 | c.3307C>G p.L1103V (on ENST00000396923; = p.L1078V on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/423 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100613527; called by muse, mutect2, varscan2
- PRKCA | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 96/529 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52578519, COSV99436217; called by muse, mutect2, varscan2
- RETSAT | c.1226A>G p.Y409C | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV99806277; called by muse, mutect2, varscan2
- SLC38A8 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs369350968; called by muse, mutect2, varscan2
- SMAD4 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100748245; called by muse, mutect2, varscan2
- SPOCK3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 76/328 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446612, COSV100692812; called by muse, mutect2, varscan2
- SRGAP1 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 36/596 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100755132; called by muse, mutect2
- ST18 | c.2371G>A p.G791R | Missense Mutation (SNP) | VAF 139/593 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52514109; called by muse, mutect2, varscan2
- SYT1 | c.167-1G>A p.X56_splice | Splice Site (SNP) | VAF 53/328 reads (16%) | catalogued as COSV99697391; called by muse, mutect2, varscan2
- TUBGCP3 | c.2720C>T p.T907M | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs536973080, COSV56187752; called by muse, mutect2, varscan2
- XRRA1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as rs761489735, COSV58499805; called by muse, mutect2, varscan2
- ZNF569 | c.476T>A p.L159H | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100386643; called by muse, mutect2, varscan2
- ZXDB | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 111/453 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100886066; called by muse, mutect2, varscan2
- CDKN2A | c.261_262dup p.E88Gfs*59 | Frame Shift Ins (INS) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- ABCC8 | c.4515C>T p.D1505= | Silent (SNP) | VAF 104/562 reads (19%) | catalogued as rs751591418, CM107102, CM112799, COSV56845944; called by muse, mutect2, varscan2
- DCC | c.828C>T p.G276= | Silent (SNP) | VAF 98/360 reads (27%) | catalogued as COSV100499966, COSV59108704; called by muse, mutect2, varscan2
- EIF2B5 | c.1635G>A p.E545= (on ENST00000647909; = p.E537= on NM_003907.3) | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV99889480; called by muse, mutect2, varscan2
- FAT3 | c.9054C>T p.S3018= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as rs764868689, COSV53135709; called by muse, mutect2
- FBXO47 | c.810G>A p.Q270= | Silent (SNP) | VAF 100/481 reads (21%) | catalogued as COSV100960883; called by muse, mutect2, varscan2
- IGF2BP3 | c.267G>A p.P89= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as rs753417877, COSV99325830; called by muse, mutect2, varscan2
- LRRC36 | c.609C>G p.P203= | Silent (SNP) | VAF 18/478 reads (4%) | catalogued as COSV99339116; called by muse, mutect2
- MYO18B | c.2052G>A p.V684= | Silent (SNP) | VAF 57/440 reads (13%) | catalogued as COSV100125160; called by muse, varscan2
- TBC1D3F | c.135C>T p.N45= | Silent (SNP) | VAF 89/271 reads (33%) | catalogued as rs1232414412; called by mutect2, varscan2
- ZNF175 | c.1953G>A p.S651= | Silent (SNP) | VAF 73/336 reads (22%) | catalogued as rs551032620, COSV51797662; called by muse, mutect2, varscan2
- ZNF423 | c.978C>T p.H326= (on ENST00000563137 / NM_001379286.1; = p.H318= on NM_015069.4) | Silent (SNP) | VAF 84/307 reads (27%) | catalogued as rs377569533; called by muse, mutect2, varscan2
- OR52A4P | n.842G>T | RNA (SNP) | VAF 73/279 reads (26%) | catalogued as rs755265491; called by muse, mutect2, varscan2
